Somatic mutation profile of tumor specimen MP2PRT-PAVLPX-TBP1-A (aliquot MP2PRT-PAVLPX-TBP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVLPX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 29.2 years (10,670 days).
Specimen MP2PRT-PAVLPX-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 881779c5-e272-4dda-bea8-bb54282c9fd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLPX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLPX-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25c387a2-b6eb-4732-bf76-31db272a971b

The open-access MAF lists 51 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Frame Shift Ins 4, Nonsense Mutation 3, 5'Flank 1, In Frame Del 1, Splice Site 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 278/278 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID5B | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 82/555 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as COSV54420831; called by muse, mutect2, varscan2
- CAPN13 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 160/330 reads (48%) | catalogued as rs1438891666, COSV54428341; called by muse, mutect2, varscan2
- CPAMD8 | c.2211+1G>A p.X737_splice (on ENST00000651564; = p.X690_splice on NM_015692.5) | Splice Site (SNP) | VAF 183/367 reads (50%) | catalogued as rs374939930; called by muse, mutect2, varscan2
- CSMD2 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 216/444 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs759533345, COSV53934650; called by muse, mutect2, varscan2
- FKBP1C | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 39/492 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs542985484, COSV62179235; called by muse, mutect2
- G6PD | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 36/775 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs782372471, COSV63703068; called by muse, mutect2
- GALE | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 152/264 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs145762332; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 263/518 reads (51%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs1478524458, COSV61476400; called by muse, varscan2
- ITIH5 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 68/492 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.157); catalogued as rs747244720, COSV56898161; called by muse, mutect2, varscan2
- KCNV1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 99/421 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52084789; called by muse, mutect2, varscan2
- KIAA0319L | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs757083721; called by muse, mutect2, varscan2
- LEXM | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 209/491 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs552406217; called by muse, mutect2, varscan2
- NADK | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 217/441 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs373135938; called by muse, mutect2, varscan2
- NMUR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 218/438 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs756384094, COSV54918385; called by muse, mutect2, varscan2
- OPCML | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 232/428 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as rs772092757, COSV100105127; called by muse, mutect2, varscan2
- PWWP2B | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 35/565 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs889431466; called by muse, mutect2
- SEC14L5 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 252/475 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs774706819, COSV52039395; called by muse, mutect2, varscan2
- UGT2B7 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 47/376 reads (13%) | catalogued as rs770419807, COSV59441898; called by muse, mutect2, varscan2
- WWC1 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 30/481 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs139653620, COSV99514164; called by muse, mutect2
- ZFHX4 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 25/482 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs1337712812, COSV50864195; called by muse, mutect2
- ZNF445 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 163/243 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748628064; called by muse, mutect2, varscan2
- ATOH7 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 159/429 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- C1QTNF5 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 60/600 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CAPN11 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GDPD4 | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 162/274 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2D | c.8358_8359insGC p.N2787Afs*7 | Frame Shift Ins (INS) | VAF 161/339 reads (47%) | called by mutect2, pindel, varscan2
- LRRTM1 | c.1255G>C p.A419P | Missense Mutation (SNP) | VAF 239/470 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MON1B | c.647_648insAGAGTCC p.Y216* | Nonsense Mutation (INS) | VAF 87/455 reads (19%) | called by mutect2, pindel, varscan2
- MUC5B | c.298_301delinsC p.N100_Y101delinsH | In Frame Del (DEL) | VAF 215/631 reads (34%) | called by pindel, varscan2*
- NASP | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR3C1 | c.955_956insGGCCA p.I319Rfs*8 | Frame Shift Ins (INS) | VAF 52/216 reads (24%) | called by pindel, varscan2*
- SEPTIN8 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 162/338 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SHC2 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAP1 | c.570dup p.L191Tfs*83 | Frame Shift Ins (INS) | VAF 213/817 reads (26%) | called by mutect2, varscan2
- TAP1 | c.569delinsCA p.L190Pfs*84 | Frame Shift Ins (INS) | VAF 209/1138 reads (18%) | called by mutect2*, pindel, varscan2*
- TRMT2B | c.632A>C p.Q211P | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- UNC79 | c.5902C>A p.P1968T (on ENST00000393151 / NM_001346218.2; = p.P1791T on NM_020818.5) | Missense Mutation (SNP) | VAF 176/368 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF765 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 88/214 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AEBP1 | c.2577T>C p.N859= | Silent (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- ARID5B | c.1992G>A p.G664= | Silent (SNP) | VAF 96/534 reads (18%) | catalogued as rs1227208072; called by muse, mutect2, varscan2
- BPI | c.891C>T p.A297= (on ENST00000262865; = p.A293= on NM_001725.3) | Silent (SNP) | VAF 36/642 reads (6%) | catalogued as rs767125785; called by muse, mutect2
- CHMP1A | c.484C>T p.L162= | Silent (SNP) | VAF 60/592 reads (10%) | called by muse, mutect2
- PCDHB10 | c.1944C>T p.G648= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as rs1315251656, COSV99503985; called by muse, mutect2, varscan2
- PCDHB9 | c.1944C>T p.G648= | Silent (SNP) | VAF 332/1535 reads (22%) | catalogued as rs1471562126, COSV53383495; called by muse, mutect2, varscan2
- SEMA3D | c.2220G>T p.R740= | Silent (SNP) | VAF 248/358 reads (69%) | called by muse, varscan2
- SETD1B | c.5856C>A p.I1952= | Silent (SNP) | VAF 69/264 reads (26%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.642C>T p.L214= | Silent (SNP) | VAF 116/466 reads (25%) | called by muse, mutect2, varscan2
- ZNHIT2 | c.1119G>A p.E373= | Silent (SNP) | VAF 86/568 reads (15%) | catalogued as rs1397271128; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-2781C>T | Intron (SNP) | VAF 145/355 reads (41%) | called by muse, mutect2, varscan2
- TRGJ2 | chr7:38253429 ins ACCCCA | 5'Flank (INS) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
